Somatic mutation profile of tumor specimen TCGA-2G-AAFY-01A (aliquot TCGA-2G-AAFY-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAFY, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 24.7 years (9,023 days).
Specimen TCGA-2G-AAFY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52039f08-01b5-4236-9273-5fe798ccff16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFY-10A (Blood Derived Normal), aliquot TCGA-2G-AAFY-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db125479-e154-4b69-8ec3-935366d74bd6

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBX2 | c.518C>A p.S173* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV60445551; called by muse, mutect2
- SLC1A7 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV101019584; called by muse, mutect2
- ALOX12B | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC6L2 | c.2129T>C p.M710T | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RAD23A | c.218T>A p.V73D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF3 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- TMEM62 | c.1456G>A p.V486M | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.071); called by muse, mutect2
- TNIP1 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF26 | c.146A>C p.N49T | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HIC2 | c.354C>A p.T118= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- PLD6 | c.294G>T p.L98= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs551772087; called by muse, mutect2, varscan2
- PRELP | c.777C>T p.N259= | Silent (SNP) | VAF 26/195 reads (13%) | catalogued as rs370979066; called by muse, mutect2, varscan2
- TIMM44 | c.708C>T p.H236= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV54493847; called by muse, mutect2, varscan2
- PRSS1 | c.200+199A>T | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as rs745314232; called by muse, mutect2
- SBDS | c.*36T>A | 3'UTR (SNP) | VAF 11/95 reads (12%) | catalogued as rs762515188; called by muse, mutect2, varscan2
